Gene-level copy-number profile of tumor specimen TCGA-06-2557-01A from TCGA case TCGA-06-2557, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 76.6 years (27,980 days).
Specimen TCGA-06-2557-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.2bf941cc-b9ef-4f50-9c89-971b0d70b4ea.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-2557-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b66f8d41-e279-4177-b7bc-11380c3eddb1

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 3: 9,499; copy number 5: 22,107; copy number 6: 19,713; copy number 7: 5,840; copy number 8: 29; copy number 9: 1,722; copy number 10: 410; copy number 11: 41; copy number 12: 39; copy number 13: 121; copy number 14: 32; copy number 15: 55; copy number 17: 100; copy number 20: 15; copy number 21: 22; copy number 22: 11; copy number 41: 11; copy number 54: 1; copy number 57: 4; copy number 69: 48.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-2557-01A-01D-0784-01): tumor purity 0.72, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 500 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:4,130,181–5,606,655, 39 genes, copy number 12: AC017000.1, CYP3A54P, AC072054.1, FOXK1, AC092428.1, AP5Z1, MIR4656, AC092610.1, RADIL, Y_RNA, PAPOLB, RPL22P16, MMD2, RNF216P1, AC092032.2, RBAK-RBAKDN, AC092032.3, AC092032.1, SPDYE19P, RBAK, RBAKDN, OR10AH1P, ZNF890P, RNU6-215P, WIPI2, SLC29A4, TNRC18, AC093620.1, AC092171.1, AC092171.4, AC092171.3, AC092171.5, FBXL18, AC092171.2, MIR589, ACTB, AC006483.2, AC006483.1, FSCN1.
- chr7:45,574,140–62,275,678, 258 genes, copy number 11–69 (broad region; genes not listed).
- chr7:73,680,918–77,416,349, 121 genes, copy number 14–17 (within-gene range 8–17) (broad region; genes not listed).
- chr7:79,768,028–80,226,181, 1 gene, copy number 20 (within-gene range 8–20): GNAI1.
- chr7:80,096,600–81,199,115, 13 genes, copy number 20: RPL10P11, RN7SL869P, AC003988.1, AC004862.1, RN7SL35P, CD36, SNRPBP1, GNAT3, AC073850.1, SEMA3C, AC004972.1, AC005008.2, AC005008.1.
- chr7:91,638,847–95,296,415, 68 genes, copy number 14–57 (within-gene range 10–57) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
